Somatic mutation profile of tumor specimen PCProject_0525_T2_WES (aliquot PCProject_0525_T2_WES_1) from CMI case PCProject_0525, project CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project. Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 72.3 years (26,395 days).
Specimen PCProject_0525_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Prostate; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d108a56-a83d-49ff-a3e3-c7dcc2626c1b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen PCProject_0525_SALIVA (Saliva), aliquot PCProject_0525_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/95f317c5-9a04-4247-8d32-82f507d52b1d

The open-access MAF lists 49 somatic variants for this specimen: 32 protein-altering or splice-affecting, 11 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 11, Intron 4, Nonsense Mutation 2, Splice Region 1, RNA 1, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CILP2 | c.371T>C p.L124P | Missense Mutation (SNP) | VAF 8/234 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs867408738; called by muse, mutect2
- FHOD1 | c.1807C>A p.P603T | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.311); catalogued as COSV99263993; called by muse, mutect2
- GRIN2D | c.1253G>C p.R418P | Missense Mutation (SNP) | VAF 56/734 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54377143; called by muse, mutect2
- KCNAB2 | c.164-7C>T | Splice Region (SNP) | VAF 29/397 reads (7%) | catalogued as rs376426842; ClinVar: likely benign; called by muse, mutect2
- KIAA1522 | c.905C>T p.P302L (on ENST00000373480 / NM_001198972.2; = p.P361L on NM_020888.3) | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs527257254, COSV53862597; called by muse, mutect2
- KLHL11 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.147); catalogued as COSV99062776; called by muse, mutect2
- MAP4K2 | c.352C>T p.R118* | Nonsense Mutation (SNP) | VAF 39/550 reads (7%) | catalogued as rs769712585, COSV99580073; called by muse, mutect2
- NEURL1B | c.1628G>A p.R543Q | Missense Mutation (SNP) | VAF 23/400 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1395745746, COSV100874746; called by muse, mutect2
- SLC36A2 | c.809G>T p.G270V | Missense Mutation (SNP) | VAF 20/516 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1370975742, COSV58865348; called by muse, mutect2
- ABCC12 | c.438C>A p.H146Q | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.105); called by muse, mutect2
- ACAP3 | c.241T>A p.F81I | Missense Mutation (SNP) | VAF 25/400 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.152); called by muse, mutect2
- ADPRH | c.155G>A p.R52K | Missense Mutation (SNP) | VAF 26/616 reads (4%) | SIFT tolerated (0.71); PolyPhen benign (0.011); called by muse, mutect2
- ADRA1B | c.1519C>T p.P507S | Missense Mutation (SNP) | VAF 26/464 reads (6%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, mutect2
- C10orf95 | c.534C>G p.D178E | Missense Mutation (SNP) | VAF 15/297 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CHUK | c.380A>T p.D127V | Missense Mutation (SNP) | VAF 8/210 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CHUK | c.379G>T p.D127Y | Missense Mutation (SNP) | VAF 8/216 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CLEC4G | c.738C>G p.S246R | Missense Mutation (SNP) | VAF 20/284 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); called by muse, mutect2
- CLVS2 | c.470G>T p.G157V | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- COL5A1 | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 30/825 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2
- DDX11 | c.292T>C p.C98R | Missense Mutation (SNP) | VAF 52/925 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.061); called by muse, mutect2
- ELN | c.31C>A p.P11T | Missense Mutation (SNP) | VAF 30/498 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MRPS34 | c.142C>A p.R48S | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.202); called by muse, mutect2
- NPTXR | c.758G>T p.R253L | Missense Mutation (SNP) | VAF 36/756 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); called by muse, mutect2
- PCNX1 | c.6519C>A p.N2173K | Missense Mutation (SNP) | VAF 20/398 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.307); called by muse, mutect2
- PKD1 | c.2201_2223del p.G734Vfs*56 | Frame Shift Del (DEL) | VAF 28/367 reads (8%) | called by mutect2, pindel
- RGS9BP | c.652G>A p.G218S | Missense Mutation (SNP) | VAF 34/415 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SLC24A2 | c.431A>G p.Y144C | Missense Mutation (SNP) | VAF 16/442 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SOX9 | c.671C>A p.P224H | Missense Mutation (SNP) | VAF 37/351 reads (11%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- TLR5 | c.121G>A p.V41I | Missense Mutation (SNP) | VAF 16/324 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.014); called by muse, mutect2
- TP53I13 | c.322C>G p.L108V | Missense Mutation (SNP) | VAF 15/293 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, mutect2
- UQCRC1 | c.478C>T p.Q160* | Nonsense Mutation (SNP) | VAF 24/443 reads (5%) | called by muse, mutect2
- ZDBF2 | c.5701T>A p.C1901S | Missense Mutation (SNP) | VAF 12/285 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2
- AXIN2 | c.1132C>T p.L378= | Silent (SNP) | VAF 20/572 reads (3%) | called by muse, mutect2
- CCDC69 | c.843C>T p.F281= | Silent (SNP) | VAF 24/724 reads (3%) | called by muse, mutect2
- GDF10 | c.666C>T p.S222= | Silent (SNP) | VAF 13/241 reads (5%) | catalogued as rs1342969265; called by muse, mutect2
- GID8 | c.336G>C p.L112= | Silent (SNP) | VAF 38/531 reads (7%) | called by muse, mutect2
- LRP5 | c.4387C>T p.L1463= | Silent (SNP) | VAF 36/554 reads (6%) | called by muse, mutect2
- MAPK8IP3 | c.2265C>G p.P755= | Silent (SNP) | VAF 27/385 reads (7%) | catalogued as rs759951795; called by muse, mutect2
- MRTFB | c.1317C>T p.S439= | Silent (SNP) | VAF 42/816 reads (5%) | catalogued as rs150298259; ClinVar: likely benign; called by muse, mutect2
- RBMXL2 | c.1178A>G p.*393= | Silent (SNP) | VAF 62/1049 reads (6%) | called by muse, mutect2
- SBF1 | c.270G>A p.E90= | Silent (SNP) | VAF 28/394 reads (7%) | catalogued as rs781618931; called by muse, mutect2
- SERPINF2 | c.978G>T p.L326= | Silent (SNP) | VAF 24/586 reads (4%) | called by muse, mutect2
- SERPINH1 | c.348C>A p.R116= | Silent (SNP) | VAF 40/992 reads (4%) | called by muse, mutect2
- ANO7 | c.2135-13C>T | Intron (SNP) | VAF 43/482 reads (9%) | catalogued as rs957647600; called by muse, mutect2
- COG7 | c.2146+18A>T | Intron (SNP) | VAF 38/690 reads (6%) | called by muse, mutect2
- ELP1 | c.3347-10G>A | Intron (SNP) | VAF 41/591 reads (7%) | called by muse, mutect2
- LINGO1-AS1 | n.369T>A | RNA (SNP) | VAF 13/258 reads (5%) | called by muse, mutect2
- R3HDML | chr20:44355702 C>T | 3'Flank (SNP) | VAF 31/565 reads (5%) | called by muse, mutect2
- SLC17A9 | c.1147+26G>A | Intron (SNP) | VAF 16/242 reads (7%) | called by muse, mutect2
